Gene-level copy-number profile of tumor specimen TCGA-42-2593-01A from TCGA case TCGA-42-2593, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.0 years (24,823 days).
Specimen TCGA-42-2593-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ae9f95e1-e3d0-4752-86b1-ca9fe03bbdd8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-42-2593-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53692110-ed9f-47f0-adf1-8dd11727f612

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,768; copy number 2: 15,335; copy number 3: 25,165; copy number 4: 9,556; copy number 5: 4,626; copy number 6: 912; copy number 7: 23; copy number 8: 186; copy number 9: 197; copy number 10: 3; copy number 11: 15; copy number 12: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-42-2593-01A-01D-1043-01): tumor purity 0.84, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 455 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:157,876,702–158,136,154, 8 genes, copy number 7: UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1.
- chr2:226,658,710–226,999,215, 6 genes, copy number 8: MIR5702, IRS1, AC010735.2, AC010735.1, RHBDD1, AC073149.1.
- chr3:163,455,568–185,825,042, 356 genes, copy number 7–12 (broad region; genes not listed).
- chr6:19,143,695–19,321,021, 2 genes, copy number 7: AL589647.1, AL357052.1.
- chr6:19,348,181–19,349,076, 1 gene, copy number 7: RPL5P20.
- chr6:77,496,119–77,496,671, 1 gene, copy number 8: RPS6P7.
- chr19:27,638,483–28,125,430, 15 genes, copy number 11: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr19:29,775,504–30,228,715, 14 genes, copy number 9: AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:36,916,329–37,832,160, 37 genes, copy number 9 (within-gene range 4–9): ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3.
- chr21:15,368,966–15,627,342, 3 genes, copy number 10 (within-gene range 2–10): AJ009632.2, CYCSP42, AJ009632.1.
- chr21:17,210,469–17,633,199, 12 genes, copy number 7–9 (within-gene range 1–9): NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1.

Autosomal genes at a single copy (total copy number 1): 1,347. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
